Somatic mutation profile of tumor specimen ALCH-AETH-TTP1-A (aliquot ALCH-AETH-TTP1-A-2-0-D-A627-36) from ALCHEMIST case ALCH-AETH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.9 years (28,073 days).
Specimen ALCH-AETH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85d0597b-b22f-4787-ab60-e723488d2048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AETH-NB1-A (Blood Derived Normal), aliquot ALCH-AETH-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf5c0f5f-5939-41aa-8f62-9a788a8cfbbe

The open-access MAF lists 74 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Nonsense Mutation 6, RNA 2, Intron 2, Frame Shift Del 1, 3'Flank 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 182/621 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 60/264 reads (23%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, varscan2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 44/240 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, varscan2
- AK5 | c.1073T>A p.L358* (on ENST00000354567 / NM_174858.3; = p.L332* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as COSV100643122; called by muse, mutect2
- ARFGAP1 | c.718-7C>A | Splice Region (SNP) | VAF 8/162 reads (5%) | catalogued as rs1433984374; called by muse, mutect2
- EPHA2 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs1290803425; called by muse, mutect2, varscan2
- EPHA5 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV56654158; called by muse, mutect2, varscan2
- MICU2 | c.1117A>T p.I373F | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1471911221; called by muse, mutect2, varscan2
- MIER2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as COSV104393219; called by muse, mutect2, varscan2
- PCDHB2 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV50564387; called by muse, mutect2, varscan2
- RAX | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56874439; called by muse, mutect2, varscan2
- SZT2 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100986948; called by muse, mutect2, varscan2
- TACR1 | c.7A>G p.N3D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1341473373; called by muse, mutect2, varscan2
- TAS2R19 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | catalogued as rs1346283387; called by muse, mutect2
- TRIM43 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55528945; called by muse, mutect2
- VCAN | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54104413; called by muse, mutect2, varscan2
- ADIPOQ | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2
- AL645922.1 | c.2933G>A p.S978N | Missense Mutation (SNP) | VAF 47/639 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2
- ARFGEF1 | c.2575A>T p.I859F | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARID4A | c.2396C>G p.T799R | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- ASTL | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BOD1L1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- CCDC175 | c.2317C>A p.H773N | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CGN | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHA2 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FBXL17 | c.477_481delinsT p.F160Wfs*197 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by pindel, varscan2*
- IFT57 | c.1242G>C p.R414S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- IL37 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- JCAD | c.827A>T p.E276V | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LHFPL6 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- LPCAT3 | c.765T>A p.Y255* | Nonsense Mutation (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.470A>T p.K157I | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2
- MUC16 | c.39442G>T p.G13148* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- PPP4R3C | c.801C>G p.Y267* | Nonsense Mutation (SNP) | VAF 51/221 reads (23%) | called by muse, mutect2, varscan2
- RAB41 | c.658A>C p.S220R (on ENST00000374473 / NM_001363807.1; = p.S219R on NM_001032726.3) | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBAK | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.38); called by muse, mutect2
- RGS1 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.255); called by muse, mutect2
- SLC39A7 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SMTNL1 | c.639C>A p.S213R (on ENST00000399154; = p.S250R on NM_001105565.2) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPON2 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- STRN4 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SUN5 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2
- TRAPPC3 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TTC21B | c.1097A>G p.Q366R | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBQLNL | c.1354C>A p.L452M | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- VAV1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- WDR62 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XPR1 | c.83T>G p.M28R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ZNF462 | c.3910C>G p.L1304V | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ACIN1 | c.1137C>T p.G379= | Silent (SNP) | VAF 90/342 reads (26%) | called by muse, mutect2, varscan2
- AXDND1 | c.756A>G p.L252= | Silent (SNP) | VAF 83/351 reads (24%) | catalogued as rs751290512; called by muse, mutect2, varscan2
- BLK | c.1113C>A p.A371= | Silent (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- BRD9 | c.732G>A p.L244= | Silent (SNP) | VAF 33/717 reads (5%) | catalogued as rs747338127; called by muse, mutect2
- CEP250 | c.3447A>T p.A1149= | Silent (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- GPR142 | c.1239C>G p.L413= | Silent (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- GPSM3 | c.168C>T p.S56= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as rs111323174; called by muse, mutect2
- HS3ST4 | c.948C>T p.F316= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- HYDIN | c.10389C>T p.G3463= | Silent (SNP) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- IGKV1D-17 | c.298C>T p.L100= | Silent (SNP) | VAF 57/551 reads (10%) | catalogued as rs539675718; called by muse, mutect2, varscan2
- LRIT2 | c.1188C>A p.L396= | Silent (SNP) | VAF 43/349 reads (12%) | called by muse, mutect2, varscan2
- MREG | c.588T>A p.V196= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- PGAM4 | c.288C>T p.T96= | Silent (SNP) | VAF 34/640 reads (5%) | catalogued as rs782394734; called by muse, mutect2
- PIEZO2 | c.6951A>G p.R2317= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- PIK3R6 | c.873C>A p.T291= | Silent (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- SLC1A2 | c.1362G>A p.L454= | Silent (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- SVEP1 | c.5481C>A p.I1827= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV52836301, COSV52841255; called by muse, mutect2
- TTBK2 | c.591A>C p.A197= | Silent (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- ZFYVE26 | c.714C>T p.L238= | Silent (SNP) | VAF 21/195 reads (11%) | called by muse, mutect2, varscan2
- ASCC2 | c.-74C>T | 5'UTR (SNP) | VAF 10/138 reads (7%) | catalogued as rs1396682552; called by muse, mutect2
- CLK2P1 | n.1098G>T | RNA (SNP) | VAF 42/606 reads (7%) | called by muse, mutect2
- GATA4 | chr8:11761823 C>T | 3'Flank (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- GGCT | c.424-656G>C | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- LCMT1 | c.404+10G>A | Intron (SNP) | VAF 40/199 reads (20%) | called by muse, mutect2, varscan2
- SLC16A6P1 | n.602T>A | RNA (SNP) | VAF 56/375 reads (15%) | called by muse, mutect2, varscan2
